Somatic mutation profile of tumor specimen TARGET-10-PANTLF-03A (aliquot TARGET-10-PANTLF-03A-01D) from TARGET case TARGET-10-PANTLF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.6 years (588 days).
Specimen TARGET-10-PANTLF-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b3357f8-de06-4c97-bc03-5d3b37d67f13.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANTLF-10A (Blood Derived Normal), aliquot TARGET-10-PANTLF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/adbfb6fa-931a-440c-9acf-c2a8f37c454f

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 2, Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OGG1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs576227046, COSV99844637; called by muse, mutect2, varscan2
- THEMIS | c.1523G>A p.R508H | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs763756804, COSV64069599; called by muse, mutect2, varscan2
- KIAA1671 | c.816C>T p.P272= | Silent (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- SKP2 | c.1062-1598C>A | Intron (SNP) | VAF 23/191 reads (12%) | catalogued as rs776235796; called by muse, mutect2, varscan2
- SYF2 | c.24+54C>A | Intron (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2, varscan2
